Somatic mutation profile of tumor specimen TCGA-VQ-A8DT-01A (aliquot TCGA-VQ-A8DT-01A-11D-A364-08) from TCGA case TCGA-VQ-A8DT, project TCGA-STAD (Stomach Adenocarcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Adenocarcinoma, intestinal type; Tissue or organ of origin: Body of stomach; AJCC pathologic stage: Stage IIIB; Tumor grade: G3; Age at diagnosis: 43.6 years (15,937 days).
Specimen TCGA-VQ-A8DT-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 5ae138f9-6bfb-4c67-97fe-42dbc7649bbe.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-VQ-A8DT-10A (Blood Derived Normal), aliquot TCGA-VQ-A8DT-10A-01D-A362-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/78a52ac0-15c3-4f74-ac05-4d1763819ea7

The open-access MAF lists 182 somatic variants for this specimen: 146 protein-altering or splice-affecting, 32 silent, 4 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 129, Silent 32, Nonsense Mutation 10, Frame Shift Del 4, RNA 2, Intron 2, Nonstop Mutation 1, Splice Site 1, Frame Shift Ins 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- SACS | c.8793dup p.R2932Tfs*7 | Frame Shift Ins (INS) | VAF 20/146 reads (14%) | catalogued as rs767871841; ClinVar: likely pathogenic / pathogenic; called by mutect2, varscan2
- TP53 | c.586C>T p.R196* | Nonsense Mutation (SNP) | VAF 12/36 reads (33%) | hotspot (GDC flag); catalogued as rs397516435, CM941329, COSV52663748, COSV53125285, COSV53128268; ClinVar: pathogenic; called by muse, mutect2, varscan2
- AARD | c.92G>A p.R31H | Missense Mutation (SNP) | VAF 4/44 reads (9%) | SIFT tolerated (0.06); PolyPhen benign (0.015); catalogued as COSV65600016; called by muse, mutect2
- ADAM20 | c.1972T>G p.W658G | Missense Mutation (SNP) | VAF 14/216 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV99833609; called by muse, mutect2
- ADAMTS16 | c.1116G>C p.L372F | Missense Mutation (SNP) | VAF 5/105 reads (5%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as rs1225921943, COSV99943228; called by muse, mutect2
- ADRA1A | c.140T>G p.V47G | Missense Mutation (SNP) | VAF 32/353 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99372347; called by muse, mutect2
- AKAP3 | c.2344G>T p.A782S | Missense Mutation (SNP) | VAF 34/126 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1475291752, COSV99962655; called by muse, mutect2
- ALOX12 | c.505G>A p.E169K | Missense Mutation (SNP) | VAF 5/39 reads (13%) | SIFT tolerated (0.09); PolyPhen benign (0.012); catalogued as rs776908949, COSV99278498; called by muse, mutect2, varscan2
- ANK1 | c.4501G>A p.D1501N | Missense Mutation (SNP) | VAF 6/51 reads (12%) | SIFT tolerated (0.09); PolyPhen benign (0.003); catalogued as rs775820344, COSV55885808; called by muse, mutect2, varscan2
- AP2A2 | c.503C>T p.A168V | Missense Mutation (SNP) | VAF 7/48 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs762001403, COSV59958043; called by muse, mutect2, varscan2
- APBA1 | c.2324G>A p.G775E | Missense Mutation (SNP) | VAF 10/71 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99597229; called by muse, mutect2, varscan2
- APOB | c.6764A>C p.K2255T | Missense Mutation (SNP) | VAF 7/66 reads (11%) | SIFT tolerated (0.07); PolyPhen benign (0.299); catalogued as rs1249838546, COSV99268346; called by muse, mutect2, varscan2
- ARF6 | c.179A>G p.N60S | Missense Mutation (SNP) | VAF 7/44 reads (16%) | SIFT tolerated, low confidence (0.07); PolyPhen probably damaging (0.998); catalogued as rs1253347869, COSV100028507; called by muse, mutect2, varscan2
- ARHGAP31 | c.2509G>A p.E837K | Missense Mutation (SNP) | VAF 10/51 reads (20%) | SIFT deleterious (0.04); PolyPhen benign (0.015); catalogued as rs775264130, COSV99957794; called by muse, mutect2, varscan2
- ATAD5 | c.4239A>C p.E1413D | Missense Mutation (SNP) | VAF 21/107 reads (20%) | SIFT tolerated (0.3); PolyPhen benign (0.043); catalogued as rs1350396788, COSV100430256; called by muse, mutect2, varscan2
- ATP8B4 | c.3283A>G p.T1095A | Missense Mutation (SNP) | VAF 10/74 reads (14%) | SIFT tolerated (0.11); PolyPhen benign (0.009); catalogued as COSV99467690; called by muse, mutect2, varscan2
- BMP1 | c.2959T>G p.*987Gext*45 | Nonstop Mutation (SNP) | VAF 5/90 reads (6%) | catalogued as COSV100115453; called by muse, mutect2
- BMPR1B | c.1404A>C p.K468N | Missense Mutation (SNP) | VAF 4/42 reads (10%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV99216297; called by muse, mutect2, varscan2
- BNC2 | c.2186C>T p.S729L | Missense Mutation (SNP) | VAF 19/107 reads (18%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.953); catalogued as rs565251984, COSV66142337; called by muse, mutect2, varscan2
- BRSK1 | c.905G>A p.R302H | Missense Mutation (SNP) | VAF 14/70 reads (20%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.891); catalogued as rs1405017626, COSV58668080; called by muse, mutect2, varscan2
- C6orf118 | c.437T>G p.F146C | Missense Mutation (SNP) | VAF 6/131 reads (5%) | SIFT tolerated (0.17); PolyPhen benign (0.443); catalogued as COSV100025213; called by muse, mutect2
- C8orf34 | c.412C>A p.R138S | Missense Mutation (SNP) | VAF 11/92 reads (12%) | SIFT tolerated (0.12); PolyPhen benign (0.065); catalogued as COSV100446353; called by muse, mutect2, varscan2
- CA10 | c.83T>C p.I28T | Missense Mutation (SNP) | VAF 14/111 reads (13%) | SIFT tolerated (1); PolyPhen benign (0.011); catalogued as COSV99560790, COSV99565340; called by muse, mutect2, varscan2
- CALCB | c.143T>C p.L48P | Missense Mutation (SNP) | VAF 5/67 reads (7%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.948); catalogued as rs1264892328, COSV100158138, COSV60834929; called by muse, mutect2
- CCDC158 | c.2660C>T p.S887F | Missense Mutation (SNP) | VAF 16/79 reads (20%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.996); catalogued as COSV66356279; called by muse, mutect2, varscan2
- CCDC88C | c.5913G>T p.Q1971H | Missense Mutation (SNP) | VAF 3/21 reads (14%) | SIFT tolerated (0.16); PolyPhen benign (0.003); catalogued as COSV57798732; called by muse, mutect2
- CCZ1 | c.898A>C p.K300Q | Missense Mutation (SNP) | VAF 13/166 reads (8%) | SIFT tolerated (0.22); PolyPhen benign (0.018); catalogued as rs759643880, COSV100382993; called by muse, mutect2, varscan2
- CD38 | c.437A>T p.E146V | Missense Mutation (SNP) | VAF 8/70 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99883098; called by muse, mutect2, varscan2
- CDC23 | c.1604A>G p.K535R | Missense Mutation (SNP) | VAF 6/74 reads (8%) | SIFT tolerated (0.19); PolyPhen benign (0.012); catalogued as COSV101203162; called by muse, mutect2
- CDH6 | c.1059T>G p.Y353* | Nonsense Mutation (SNP) | VAF 13/66 reads (20%) | catalogued as COSV99420981; called by muse, mutect2, varscan2
- CEP68 | c.1429G>A p.E477K | Missense Mutation (SNP) | VAF 14/63 reads (22%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.691); catalogued as COSV99561311; called by muse, mutect2, varscan2
- CFHR3 | c.520A>G p.K174E | Missense Mutation (SNP) | VAF 9/62 reads (15%) | SIFT tolerated (1); PolyPhen benign (0.101); catalogued as COSV100807823; called by muse, mutect2, varscan2
- CLUH | c.3331G>A p.G1111R (on ENST00000435359; = p.G1150R on NM_015229.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 11/51 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs1442398511, COSV70929407; called by muse, mutect2, varscan2
- COL11A1 | c.5129T>C p.F1710S | Missense Mutation (SNP) | VAF 8/86 reads (9%) | SIFT deleterious (0.01); PolyPhen benign (0.049); catalogued as rs1249324579, COSV100618128; called by muse, mutect2
- CPNE3 | c.46G>T p.A16S | Missense Mutation (SNP) | VAF 17/112 reads (15%) | SIFT tolerated (0.11); PolyPhen benign (0.001); catalogued as rs1301384868, COSV99548147; called by muse, mutect2, varscan2
- CRB1 | c.2881A>C p.I961L | Missense Mutation (SNP) | VAF 10/103 reads (10%) | SIFT tolerated (0.45); PolyPhen benign (0.038); catalogued as COSV100958086; called by muse, mutect2, varscan2
- CSMD1 | c.9610G>A p.G3204S (on ENST00000520002; = p.G3203S on NM_033225.6) | Missense Mutation (SNP) | VAF 8/47 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1259302833, COSV59403684; called by muse, mutect2, varscan2
- DCN | c.187C>T p.R63* | Nonsense Mutation (SNP) | VAF 13/91 reads (14%) | catalogued as rs1433795573, COSV50008133; called by muse, mutect2, varscan2
- DNAH5 | c.6614T>A p.I2205N | Missense Mutation (SNP) | VAF 7/80 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); catalogued as COSV99454632; called by muse, mutect2
- DNAH6 | c.1768G>A p.D590N | Missense Mutation (SNP) | VAF 4/66 reads (6%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.762); catalogued as COSV99408926; called by muse, mutect2
- DNAH9 | c.7232T>G p.F2411C | Missense Mutation (SNP) | VAF 8/84 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV99308365; called by muse, mutect2
- DUOXA2 | c.542C>A p.S181* | Nonsense Mutation (SNP) | VAF 5/28 reads (18%) | catalogued as COSV50994091; called by muse, mutect2, varscan2
- DYNC1I1 | c.460A>C p.T154P | Missense Mutation (SNP) | VAF 13/218 reads (6%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.808); catalogued as COSV100269386; called by muse, mutect2
- EIF2B4 | c.352A>G p.R118G (on ENST00000347454 / NM_001034116.2; = p.R117G on NM_015636.3) | Missense Mutation (SNP) | VAF 11/107 reads (10%) | SIFT tolerated (0.07); PolyPhen benign (0.321); catalogued as COSV99278027; called by muse, mutect2, varscan2
- EML1 | c.540C>A p.F180L | Missense Mutation (SNP) | VAF 23/136 reads (17%) | SIFT tolerated (0.17); PolyPhen benign (0.005); catalogued as COSV99215707; called by muse, mutect2, varscan2
- EPHA7 | c.2357A>C p.D786A | Missense Mutation (SNP) | VAF 6/67 reads (9%) | SIFT deleterious (0); PolyPhen benign (0.172); catalogued as COSV100994402; called by muse, mutect2
- FAT3 | c.6074A>C p.K2025T | Missense Mutation (SNP) | VAF 14/43 reads (33%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.6); catalogued as COSV53148006, COSV99035557; called by muse, mutect2, varscan2
- FBN1 | c.836T>G p.L279R | Missense Mutation (SNP) | VAF 48/338 reads (14%) | SIFT tolerated (0.35); PolyPhen benign (0.096); catalogued as COSV100356497; called by muse, mutect2, varscan2
- FBN3 | c.5845G>A p.E1949K | Missense Mutation (SNP) | VAF 7/24 reads (29%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.995); catalogued as rs1328150230, COSV54464780; called by muse, mutect2, varscan2
- GCAT | c.833C>T p.P278L | Missense Mutation (SNP) | VAF 19/83 reads (23%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.857); catalogued as COSV99959957; called by muse, mutect2, varscan2
- GDA | c.760T>G p.L254V | Missense Mutation (SNP) | VAF 8/160 reads (5%) | SIFT deleterious (0.02); PolyPhen benign (0.09); catalogued as COSV52992212, COSV99429796; called by muse, mutect2
- GDNF | c.344A>C p.N115T | Missense Mutation (SNP) | VAF 7/113 reads (6%) | SIFT tolerated (0.35); PolyPhen benign (0.377); catalogued as COSV100427587; called by muse, mutect2
- GPATCH4 | c.67C>A p.Q23K | Missense Mutation (SNP) | VAF 9/82 reads (11%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as COSV100577006; called by muse, mutect2, varscan2
- GRIN3A | c.1393A>T p.I465F | Missense Mutation (SNP) | VAF 9/194 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.969); catalogued as COSV100701878; called by muse, mutect2
- HEATR5B | c.3137C>T p.A1046V | Missense Mutation (SNP) | VAF 8/49 reads (16%) | SIFT deleterious (0.01); PolyPhen benign (0.219); catalogued as rs1192674798, COSV99250305; called by muse, mutect2, varscan2
- HNRNPH3 | c.835G>A p.G279S | Missense Mutation (SNP) | VAF 10/72 reads (14%) | SIFT tolerated (0.61); PolyPhen benign (0.005); catalogued as COSV99769501; called by muse, mutect2, varscan2
- HSPD1 | c.510G>T p.Q170H | Missense Mutation (SNP) | VAF 8/56 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.914); catalogued as COSV99291577; called by muse, mutect2, varscan2
- HSPH1 | c.1790C>T p.P597L | Missense Mutation (SNP) | VAF 11/73 reads (15%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.996); catalogued as COSV60710925; called by muse, mutect2, varscan2
- IL13RA1 | c.463G>A p.D155N | Missense Mutation (SNP) | VAF 44/105 reads (42%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.984); catalogued as rs762448978, COSV100861755, COSV65427044; called by muse, mutect2, varscan2
- ITGAD | c.2056C>T p.R686C | Missense Mutation (SNP) | VAF 50/275 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs763655950, COSV66757872; called by muse, mutect2, varscan2
- KCNK5 | c.26C>A p.T9N | Missense Mutation (SNP) | VAF 10/68 reads (15%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.854); catalogued as COSV100851946; called by muse, mutect2
- KLHL1 | c.1138A>G p.M380V | Missense Mutation (SNP) | VAF 15/96 reads (16%) | SIFT tolerated (0.06); PolyPhen benign (0.304); catalogued as COSV100918211; called by muse, mutect2, varscan2
- KRIT1 | c.502C>T p.H168Y | Missense Mutation (SNP) | VAF 13/69 reads (19%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.885); catalogued as COSV100388958; called by muse, mutect2, varscan2
- KRT82 | c.916G>A p.E306K | Missense Mutation (SNP) | VAF 15/59 reads (25%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.93); catalogued as rs376327776; called by muse, mutect2, varscan2
- LCE2A | c.300C>A p.H100Q | Missense Mutation (SNP) | VAF 4/82 reads (5%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0); catalogued as COSV100909220; called by muse, mutect2
- LHX4 | c.998C>T p.T333M | Missense Mutation (SNP) | VAF 37/302 reads (12%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.513); catalogued as rs780869144, COSV99761908; ClinVar: uncertain significance; called by muse, mutect2
- LYVE1 | c.10T>G p.C4G | Missense Mutation (SNP) | VAF 6/35 reads (17%) | SIFT tolerated (0.31); PolyPhen benign (0); catalogued as COSV99811206; called by muse, mutect2, varscan2
- LYVE1 | c.9G>T p.R3S | Missense Mutation (SNP) | VAF 5/34 reads (15%) | SIFT tolerated (0.08); PolyPhen benign (0.001); catalogued as COSV99811208; called by muse, mutect2, varscan2
- MAGEB4 | c.771C>A p.Y257* | Nonsense Mutation (SNP) | VAF 17/38 reads (45%) | catalogued as COSV100975120; called by muse, mutect2, varscan2
- MINAR1 | c.38A>C p.K13T | Missense Mutation (SNP) | VAF 10/64 reads (16%) | SIFT tolerated (0.11); PolyPhen benign (0.074); catalogued as COSV100549335; called by muse, mutect2, varscan2
- MUC17 | c.7763G>A p.S2588N | Missense Mutation (SNP) | VAF 63/470 reads (13%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.483); catalogued as COSV100075201; called by muse, mutect2, varscan2
- MYH13 | c.4543G>A p.D1515N | Missense Mutation (SNP) | VAF 11/45 reads (24%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.986); catalogued as rs760905233, COSV99355610; called by muse, mutect2, varscan2
- NAPB | c.688G>A p.E230K | Missense Mutation (SNP) | VAF 6/110 reads (5%) | SIFT deleterious (0.05); PolyPhen benign (0.135); catalogued as COSV100794116; called by muse, mutect2
- NFATC2 | c.2467G>A p.G823R | Missense Mutation (SNP) | VAF 21/104 reads (20%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.731); catalogued as rs528842461, COSV101044759; called by muse, mutect2, varscan2
- NGDN | c.620G>A p.R207H | Missense Mutation (SNP) | VAF 11/37 reads (30%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.893); catalogued as rs566567181, COSV101238937; called by muse, mutect2, varscan2
- NOTCH4 | c.3520G>A p.G1174R | Missense Mutation (SNP) | VAF 6/37 reads (16%) | SIFT tolerated (0.16); PolyPhen possibly damaging (0.47); catalogued as rs775047010, COSV66679031; called by muse, mutect2, varscan2
- NPR1 | c.582G>C p.E194D | Missense Mutation (SNP) | VAF 4/21 reads (19%) | SIFT tolerated (0.07); PolyPhen benign (0); catalogued as rs780404659, COSV100903826; called by muse, mutect2
- OMP | c.196G>A p.E66K | Missense Mutation (SNP) | VAF 4/40 reads (10%) | SIFT tolerated, low confidence (0.33); PolyPhen benign (0.063); catalogued as rs782214575, COSV53692792; called by mutect2, varscan2
- OR13G1 | c.636C>A p.C212* | Nonsense Mutation (SNP) | VAF 5/51 reads (10%) | catalogued as rs577553531, COSV100687354, COSV62944955; called by mutect2, varscan2
- OR51B2 | c.301T>A p.F101I | Missense Mutation (SNP) | VAF 3/40 reads (8%) | SIFT deleterious (0.02); PolyPhen benign (0.02); catalogued as COSV100173542, COSV60916997; called by muse, mutect2
- OR6B1 | c.70C>T p.R24W | Missense Mutation (SNP) | VAF 10/93 reads (11%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.453); catalogued as rs371188814; called by muse, mutect2, varscan2
- OSBPL6 | c.1997G>A p.R666H | Missense Mutation (SNP) | VAF 57/287 reads (20%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.829); catalogued as rs146931219, COSV51918300; called by muse, mutect2, varscan2
- P2RY14 | c.728T>G p.F243C | Missense Mutation (SNP) | VAF 13/117 reads (11%) | SIFT deleterious (0.04); PolyPhen benign (0.038); catalogued as COSV56374175; called by muse, mutect2, varscan2
- PABPC3 | c.89A>C p.K30T | Missense Mutation (SNP) | VAF 15/69 reads (22%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.51); catalogued as COSV99878822; called by muse, mutect2, varscan2
- PAGE3 | c.322G>T p.E108* | Nonsense Mutation (SNP) | VAF 4/49 reads (8%) | catalogued as COSV100892022; called by muse, mutect2
- PCDH15 | c.851C>T p.A284V | Missense Mutation (SNP) | VAF 8/73 reads (11%) | SIFT tolerated (0.1); PolyPhen benign (0.443); catalogued as rs777071595, COSV100228163; ClinVar: uncertain significance; called by muse, mutect2
- PCDHB7 | c.2276C>A p.T759K | Missense Mutation (SNP) | VAF 11/145 reads (8%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.461); catalogued as COSV50805732; called by muse, mutect2
- PDE11A | c.1976G>A p.R659Q | Missense Mutation (SNP) | VAF 13/86 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs760731175, COSV99615305; called by muse, mutect2, varscan2
- PDE3A | c.902C>T p.S301F | Missense Mutation (SNP) | VAF 6/40 reads (15%) | SIFT deleterious (0); PolyPhen possibly damaging (0.77); catalogued as COSV100762857; called by muse, mutect2, varscan2
- PHF3 | c.2866G>A p.A956T | Missense Mutation (SNP) | VAF 4/53 reads (8%) | SIFT tolerated (0.1); PolyPhen benign (0.005); catalogued as COSV100014050; called by muse, mutect2
- PLXDC2 | c.461G>A p.R154Q | Missense Mutation (SNP) | VAF 13/64 reads (20%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.994); catalogued as rs372746008; called by muse, mutect2, varscan2
- PMEL | c.1555G>A p.G519R | Missense Mutation (SNP) | VAF 6/25 reads (24%) | SIFT tolerated (0.07); PolyPhen benign (0.197); catalogued as rs199615476, COSV100092645, COSV100093263; called by muse, mutect2, varscan2
- PPP1R9A | c.790C>T p.R264* | Nonsense Mutation (SNP) | VAF 7/65 reads (11%) | catalogued as rs1179023566, COSV99199245; called by muse, mutect2, varscan2
- PRB4 | c.631G>T p.G211C | Missense Mutation (SNP) | VAF 26/182 reads (14%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.884); catalogued as rs1345823917, COSV99686838; called by muse, mutect2, varscan2
- PROKR2 | c.842T>C p.L281P | Missense Mutation (SNP) | VAF 4/36 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV54088230, COSV99450687; called by muse, mutect2
- PSG6 | c.235A>G p.I79V | Missense Mutation (SNP) | VAF 51/317 reads (16%) | SIFT deleterious (0.03); PolyPhen benign (0.251); catalogued as rs1309872431, COSV51836945; called by muse, mutect2, varscan2
- PWWP3B | c.434T>A p.L145H | Missense Mutation (SNP) | VAF 3/23 reads (13%) | SIFT tolerated (0.23); PolyPhen possibly damaging (0.873); catalogued as COSV100530866, COSV100531663; called by muse, mutect2
- RBMS1 | c.665A>C p.K222T | Missense Mutation (SNP) | VAF 30/153 reads (20%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.983); catalogued as COSV100817109; called by muse, mutect2, varscan2
- RNF6 | c.2051A>T p.N684I | Missense Mutation (SNP) | VAF 10/75 reads (13%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.015); catalogued as COSV100644683; called by mutect2, varscan2
- RPL10L | c.593A>C p.K198T | Missense Mutation (SNP) | VAF 21/68 reads (31%) | SIFT deleterious (0.01); PolyPhen benign (0.033); catalogued as rs934538643, COSV53560855, COSV53561906; called by muse, mutect2, varscan2
- SAXO1 | c.1108T>G p.C370G | Missense Mutation (SNP) | VAF 7/42 reads (17%) | SIFT tolerated (0.36); PolyPhen benign (0.001); catalogued as COSV101000209; called by muse, mutect2, varscan2
- SCN10A | c.2909G>T p.S970I | Missense Mutation (SNP) | VAF 9/63 reads (14%) | SIFT tolerated (0.21); PolyPhen benign (0.048); catalogued as COSV101479547; called by muse, mutect2, varscan2
- SELENOW | c.157G>T p.A53S | Missense Mutation (SNP) | VAF 9/250 reads (4%) | SIFT tolerated (0.56); PolyPhen benign (0.303); catalogued as COSV101549502; called by muse, mutect2
- SEMA7A | c.1732C>T p.R578C | Missense Mutation (SNP) | VAF 21/109 reads (19%) | SIFT tolerated (0.16); PolyPhen possibly damaging (0.882); catalogued as rs763712355, COSV99985028; called by muse, mutect2, varscan2
- SFMBT2 | c.1203+2T>C p.X401_splice | Splice Site (SNP) | VAF 3/48 reads (6%) | catalogued as COSV100739703; called by muse, mutect2
- SLC28A2 | c.203G>T p.S68I | Missense Mutation (SNP) | VAF 16/129 reads (12%) | SIFT tolerated (0.09); PolyPhen benign (0.211); catalogued as COSV100754828; called by muse, mutect2, varscan2
- SLC39A12 | c.2008T>C p.F670L (on ENST00000377369 / NM_001145195.2; = p.F633L on NM_152725.3) | Missense Mutation (SNP) | VAF 10/111 reads (9%) | SIFT tolerated (1); PolyPhen benign (0.006); catalogued as COSV101070175, COSV101070189; called by muse, mutect2
- SLC46A3 | c.1027G>A p.A343T | Missense Mutation (SNP) | VAF 15/118 reads (13%) | SIFT deleterious (0.01); PolyPhen benign (0.341); catalogued as rs201296960, COSV99906557; called by muse, mutect2, varscan2
- SMARCB1 | c.119G>A p.R40Q | Missense Mutation (SNP) | VAF 26/147 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV54093822; called by muse, mutect2, varscan2
- SPSB2 | c.17T>C p.L6P | Missense Mutation (SNP) | VAF 6/40 reads (15%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.104); catalogued as COSV99222995; called by muse, mutect2, varscan2
- SPTA1 | c.6404C>A p.S2135Y | Missense Mutation (SNP) | VAF 12/160 reads (8%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.637); catalogued as COSV100935636; called by muse, mutect2
- SPTBN4 | c.4601G>A p.R1534Q | Missense Mutation (SNP) | VAF 5/28 reads (18%) | SIFT deleterious (0.01); PolyPhen benign (0.019); catalogued as rs1475447434, COSV100152227; called by muse, mutect2
- SRL | c.1025T>C p.I342T | Missense Mutation (SNP) | VAF 10/169 reads (6%) | SIFT tolerated (0.17); PolyPhen probably damaging (0.996); catalogued as COSV101281371; called by muse, mutect2
- STK11IP | c.2276A>G p.K759R | Missense Mutation (SNP) | VAF 4/32 reads (13%) | SIFT tolerated (0.23); PolyPhen benign (0.025); catalogued as COSV99823493; called by muse, mutect2
- SVEP1 | c.2176C>T p.P726S | Missense Mutation (SNP) | VAF 7/22 reads (32%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.727); catalogued as rs772454423, COSV100239174; called by muse, mutect2, varscan2
- TAFA2 | c.364A>T p.N122Y | Missense Mutation (SNP) | VAF 6/63 reads (10%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.995); catalogued as COSV101353995; called by muse, mutect2
- TAL2 | c.134G>C p.R45P | Missense Mutation (SNP) | VAF 7/33 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100482515, COSV61883785; called by muse, mutect2, varscan2
- TLR7 | c.2752G>T p.D918Y | Missense Mutation (SNP) | VAF 22/76 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.95); catalogued as COSV101028170; called by muse, mutect2, varscan2
- TMEM94 | c.3472C>T p.Q1158* | Nonsense Mutation (SNP) | VAF 18/119 reads (15%) | catalogued as rs1297252008, COSV100050990; called by muse, mutect2, varscan2
- TMPRSS4 | c.283A>G p.S95G | Missense Mutation (SNP) | VAF 16/101 reads (16%) | SIFT tolerated (0.32); PolyPhen benign (0.039); catalogued as rs1278092370, COSV101449435; called by muse, mutect2, varscan2
- TNP1 | c.97T>C p.Y33H | Missense Mutation (SNP) | VAF 24/138 reads (17%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.959); catalogued as rs776944785, COSV99378644; called by muse, mutect2, varscan2
- TPPP | c.167G>A p.R56Q | Missense Mutation (SNP) | VAF 4/28 reads (14%) | SIFT tolerated (0.45); PolyPhen benign (0.143); catalogued as rs751569987, COSV100862904; called by muse, mutect2
- TRAK2 | c.1621A>T p.I541F | Missense Mutation (SNP) | VAF 12/132 reads (9%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as COSV100217182; called by muse, mutect2
- TTN | c.187G>A p.A63T | Missense Mutation (SNP) | VAF 25/85 reads (29%) | PolyPhen probably damaging (0.997); catalogued as rs764892312, COSV100588460, COSV60218568; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- ULK4 | c.2216G>A p.R739H | Missense Mutation (SNP) | VAF 11/112 reads (10%) | SIFT tolerated (0.1); PolyPhen benign (0.003); catalogued as rs757472548, COSV57228103; called by muse, mutect2, varscan2
- UNC5A | c.985C>T p.R329W | Missense Mutation (SNP) | VAF 6/26 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs150032228; called by muse, mutect2, varscan2
- WEE1 | c.1385G>A p.G462D | Missense Mutation (SNP) | VAF 21/102 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100219834; called by muse, mutect2, varscan2
- WNK3 | c.4823A>C p.N1608T | Missense Mutation (SNP) | VAF 6/45 reads (13%) | SIFT deleterious (0.01); PolyPhen benign (0.049); catalogued as COSV100672190; called by muse, mutect2, varscan2
- WNT9B | c.514T>C p.F172L | Missense Mutation (SNP) | VAF 9/34 reads (26%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.992); catalogued as COSV99255398; called by muse, mutect2, varscan2
- YEATS2 | c.2189G>A p.S730N | Missense Mutation (SNP) | VAF 8/50 reads (16%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.549); catalogued as COSV100528347; called by muse, mutect2, varscan2
- YKT6 | c.31A>G p.K11E | Missense Mutation (SNP) | VAF 7/37 reads (19%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.974); catalogued as rs1188872212, COSV99790724; called by muse, mutect2, varscan2
- ZNF350 | c.856G>T p.G286* | Nonsense Mutation (SNP) | VAF 25/172 reads (15%) | catalogued as COSV99702729; called by muse, mutect2, varscan2
- ZNF354C | c.641A>G p.K214R | Missense Mutation (SNP) | VAF 10/65 reads (15%) | SIFT tolerated (0.06); PolyPhen benign (0.003); catalogued as COSV100203813; called by muse, mutect2, varscan2
- ZNF418 | c.1133G>A p.C378Y | Missense Mutation (SNP) | VAF 17/134 reads (13%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.492); catalogued as COSV101269024; called by muse, mutect2, varscan2
- ZNF516 | c.2056G>A p.V686I | Missense Mutation (SNP) | VAF 14/35 reads (40%) | SIFT tolerated (0.39); PolyPhen benign (0); catalogued as rs368813175, COSV101487375; called by muse, mutect2, varscan2
- ZNF521 | c.2982G>T p.K994N | Missense Mutation (SNP) | VAF 8/66 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100833504; called by muse, mutect2, varscan2
- ZNF546 | c.2326C>A p.P776T | Missense Mutation (SNP) | VAF 6/61 reads (10%) | SIFT deleterious (0); PolyPhen possibly damaging (0.649); catalogued as COSV100713563; called by muse, mutect2, varscan2
- ZNF646 | c.4744G>A p.A1582T | Missense Mutation (SNP) | VAF 16/96 reads (17%) | SIFT tolerated (0.3); PolyPhen benign (0.005); catalogued as rs746511789, COSV54925166; called by muse, mutect2, varscan2
- FRG2C | c.60C>A p.D20E | Missense Mutation (SNP) | VAF 10/148 reads (7%) | SIFT tolerated (0.18); PolyPhen benign (0.259); called by muse, mutect2
- IGHG1 | c.659C>G p.S220C | Missense Mutation (SNP) | VAF 26/298 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.925); called by muse, mutect2
- POLR2A | c.4013C>T p.T1338M | Missense Mutation (SNP) | VAF 3/21 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- POU2F3 | c.877del p.R293Afs*2 | Frame Shift Del (DEL) | VAF 11/79 reads (14%) | called by mutect2, pindel, varscan2
- RGS7 | c.996del p.F332Lfs*7 | Frame Shift Del (DEL) | VAF 49/159 reads (31%) | called by mutect2, pindel, varscan2
- RNF43 | c.147_148del p.R49Sfs*25 | Frame Shift Del (DEL) | VAF 16/78 reads (21%) | called by pindel, varscan2
- STS | c.293_324del p.L98Rfs*2 | Frame Shift Del (DEL) | VAF 20/54 reads (37%) | called by mutect2, pindel
- TET1 | c.6127C>T p.R2043C | Missense Mutation (SNP) | VAF 5/58 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.966); called by muse, mutect2
- ACKR3 | c.567G>A p.A189= | Silent (SNP) | VAF 15/85 reads (18%) | catalogued as rs139490851, COSV56024154; called by muse, mutect2, varscan2
- ADAM9 | c.15G>A p.A5= | Silent (SNP) | VAF 5/51 reads (10%) | catalogued as rs775495452, COSV101166285; called by muse, mutect2
- ADAMTS14 | c.958C>T p.L320= | Silent (SNP) | VAF 11/67 reads (16%) | catalogued as rs1307130987, COSV100941893; called by muse, mutect2, varscan2
- ALPL | c.540C>T p.H180= | Silent (SNP) | VAF 8/28 reads (29%) | catalogued as rs770068340, COSV100876969; called by muse, mutect2, varscan2
- ANO2 | c.963C>T p.D321= (on ENST00000356134 / NM_001278597.3; = p.D325= on NM_001278596.3) | Silent (SNP) | VAF 18/73 reads (25%) | catalogued as rs571512821, COSV59031666; called by muse, mutect2, varscan2
- ATP1A3 | c.2187G>A p.K729= (on ENST00000545399 / NM_001256214.2; = p.K716= on NM_152296.5) | Silent (SNP) | VAF 19/150 reads (13%) | catalogued as COSV57489271; called by muse, mutect2, varscan2
- C5AR2 | c.930C>T p.A310= | Silent (SNP) | VAF 11/52 reads (21%) | catalogued as rs373635111; called by muse, mutect2, varscan2
- CDH6 | c.1329G>A p.S443= | Silent (SNP) | VAF 16/129 reads (12%) | catalogued as rs142200699; called by muse, mutect2, varscan2
- DAGLB | c.1242C>T p.Y414= | Silent (SNP) | VAF 11/62 reads (18%) | catalogued as rs771458012, COSV99766003; called by muse, mutect2, varscan2
- DLX3 | c.735C>T p.D245= | Silent (SNP) | VAF 12/29 reads (41%) | catalogued as rs147724731; called by muse, mutect2, varscan2
- DNAH11 | c.5991G>A p.P1997= | Silent (SNP) | VAF 30/173 reads (17%) | catalogued as rs763685245, COSV100181087; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- ERGIC1 | c.822C>T p.I274= | Silent (SNP) | VAF 11/68 reads (16%) | catalogued as COSV101195071; called by muse, mutect2, varscan2
- GTF2IRD1 | c.2571C>T p.I857= (on ENST00000265755 / NM_016328.3; = p.I842= on NM_005685.4) | Silent (SNP) | VAF 19/87 reads (22%) | catalogued as COSV99735642; called by muse, mutect2, varscan2
- H2BC9 | c.264G>C p.S88= | Silent (SNP) | VAF 8/108 reads (7%) | catalogued as rs1489147078, COSV55099128; called by muse, mutect2
- HAO1 | c.309G>A p.T103= | Silent (SNP) | VAF 6/34 reads (18%) | catalogued as rs758582298, COSV101113286, COSV101113336; called by muse, mutect2, varscan2
- HOXB4 | c.417C>T p.P139= | Silent (SNP) | VAF 11/44 reads (25%) | catalogued as rs1377213999, COSV100203722, COSV100203863; called by muse, mutect2, varscan2
- KCNA5 | c.1227C>T p.R409= | Silent (SNP) | VAF 6/46 reads (13%) | catalogued as COSV99364236; called by muse, mutect2
- KCNQ3 | c.423C>A p.V141= | Silent (SNP) | VAF 6/48 reads (13%) | catalogued as COSV101196486; called by muse, mutect2
- MUC16 | c.16995T>G p.T5665= | Silent (SNP) | VAF 3/26 reads (12%) | catalogued as COSV101201855; called by muse, mutect2
- NACC2 | c.1044G>A p.L348= | Silent (SNP) | VAF 15/50 reads (30%) | catalogued as rs755165066, COSV99508567; called by muse, mutect2, varscan2
- NANS | c.939C>T p.T313= | Silent (SNP) | VAF 9/55 reads (16%) | catalogued as rs199607636, COSV52964707, COSV99271550; called by muse, varscan2
- NCAM1 | c.2286A>G p.K762= (on ENST00000316851 / NM_181351.5; = p.K752= on NM_000615.7) | Silent (SNP) | VAF 5/67 reads (7%) | catalogued as COSV100378657; called by muse, mutect2
- NPAP1 | c.2610A>G p.Q870= | Silent (SNP) | VAF 8/52 reads (15%) | catalogued as COSV61505654, COSV61506061; called by mutect2, varscan2
- OR11L1 | c.138C>A p.I46= | Silent (SNP) | VAF 3/27 reads (11%) | catalogued as COSV100869497; called by muse, mutect2
- OR8B12 | c.648T>G p.S216= | Silent (SNP) | VAF 4/14 reads (29%) | catalogued as COSV100172957; called by mutect2, varscan2
- PSG6 | c.234C>T p.Y78= | Silent (SNP) | VAF 51/316 reads (16%) | catalogued as rs1255856694, COSV99414637; called by muse, mutect2, varscan2
- RNF213 | c.9651C>T p.V3217= | Silent (SNP) | VAF 4/30 reads (13%) | catalogued as COSV100301597; called by muse, mutect2, varscan2
- SLC22A8 | c.285C>T p.C95= | Silent (SNP) | VAF 11/114 reads (10%) | catalogued as COSV100268118; called by muse, mutect2, varscan2
- THSD4 | c.2667G>T p.V889= | Silent (SNP) | VAF 10/85 reads (12%) | catalogued as rs1271792879, COSV99967277; called by muse, mutect2, varscan2
- TRPM2 | c.3426G>A p.Q1142= | Silent (SNP) | VAF 26/129 reads (20%) | catalogued as COSV100309367, COSV99038960; called by muse, mutect2, varscan2
- VSIG10 | c.648C>T p.T216= | Silent (SNP) | VAF 7/26 reads (27%) | catalogued as rs771151263, COSV63653712; called by muse, mutect2, varscan2
- ZNF25 | c.939C>T p.P313= | Silent (SNP) | VAF 3/40 reads (8%) | catalogued as COSV100224586, COSV100224799; called by muse, mutect2
- DCHS2 | n.3168G>A | RNA (SNP) | VAF 5/56 reads (9%) | catalogued as COSV100253319; called by muse, mutect2
- GABRE | c.784+1190A>C | Intron (SNP) | VAF 38/85 reads (45%) | catalogued as rs1323267730, COSV100944225; called by muse, mutect2, varscan2
- KANSL2 | c.1228-1624C>T | Intron (SNP) | VAF 3/32 reads (9%) | catalogued as COSV101102083; called by muse, mutect2
- OR2W5 | n.870G>T | RNA (SNP) | VAF 8/126 reads (6%) | called by muse, mutect2
